Surgical pathology report (de-identified scan), TCGA case TCGA-FB-AAPP, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Asterand, specimen TCGA-FB-AAPP-01A (Primary Tumor).

[page 1 of 3]
TSS Patient ID:

Surgical Date:

Gross Description: Whipple

specimen consisting of stomach, measuring 11.2 x 10 x

3.5 cm with a proximal staple line which measures 10.5 cm, duodenum

measuring 28 cm in length x

3.5-4 cm in diameter to distal staple margin and pancreatic head measuring

7.5 x 7 x 5.5 cm. There is a clear tan mucinous material protruding from

the main pancreatic duct at the neck margin, but the main pancreatic duct

remains probe patent. The common bile duct is 0.7 cm in diameter and is

probe patent through the ampulla. The pancreas is serially sectioned to

reveal a main pancreatic duct which is dilated to 3 cm in diameter, with

clear tan-red mucinous mass, measuring 5.5 x 3.5 x 3 cm inside the duct.

The mass is largely mucinous and cystic with some solid papillary areas and

appears to be encapsulated within the duct throughout the pancreas. It is

approximately 0.5 cm from the closest radial margin (anterior medial

margin). There is an adjacent

area of firm tan-white slightly lobular pancreas, possibly consistent with

chronic pancreatitis. The stomach is covered by smooth tan-red serosa and

opened along the greater curvature to reveal unremarkable mucosa. The

duodenum is covered by focal green-yellow discoloration of the proximal

serosa and is opened to reveal 1 mL of blood clot adherent to the ampulla

with possible mucinous material. The ampulla is 12.5 cm from the proximal

stomach margin and 17 cm from the distal duodenal margin. The greater

curvature fat measures 11 x 3.2 x 2 cm and is serially sectioned and

IGD-03
Adenocarcinoma, duct NOS 8504/3
Site: Pancreas head C25.0
JES 5/16/14

[page 2 of 3]
palpated to reveal the presence of no obvious lymph nodes. The lesser curvature fat measures 5.5 x 5 x 2.5 cm and is serially sectioned and palpated to reveal the presence of six possible lymph nodes. Gross sectioning and palpation of the peripancreatic fat reveals the presence of 20 possible lymph nodes, the largest of which measures 0.6 x 0.4 x 0.2 cm.

Microscopic Description:

Diagnosis Details: Invasive ductal adenocarcinoma, approx. 5.5 cm, moderately to poorly differentiated

- Invasive tumor arises in a background of IPMN with low to high-grade dysplasia
- Tumor extensively involves peripancreatic soft tissue
- Tumor infiltrates: portal vein muscular media, common bile duct adventitia and duodenal mucosa
- Multifocal perineural invasion and angiolymphatic invasion present (including within peripancreatic soft tissue)
- Cauterized tumor present in peripancreatic soft tissue within 0.1 cm of pancreatic neck margin of excision where there is also perineural/angiolymphatic invasion (please see diagnoses for specimens C and F)
- Extensive changes of chronic pancreatitis
- Radial surgical margins free of tumor
- Mucosal surgical margins free of tumor
- Metastatic adenocarcinoma present in three of seven peripancreatic lymph nodes (3/7); focal extracapsular extension present in one of the positive lymph nodes
- AJCC stage: T3 N1 Mx (inclusive of all specimens)

Comments:

Formatted Path Reports: PANCREAS TISSUE CHECKLIST

Specimen type: Whipple resection

Tumor site: Head

Tumor size: 5.5 cm

[page 3 of 3]
Histologic type: Adenocarcinoma, ductal type

Histologic grade: Poorly to moderately differentiated

Tumor extent: Other - portal vein muscular media, common bile duct adventitia and duodenal mucosa

Lymph nodes: 3/7 positive for metastasis (Regional 3/7)

Lymphatic invasion: Present

Venous invasion: Present

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Source: NCI Genomic Data Commons file 75bd4306-5406-4afb-86bd-9485c127c3c3 (TCGA-FB-AAPP.BC5C078D-5731-4128-AA6D-201FBDE712BD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).